Somatic mutation profile of tumor specimen TCGA-CN-4742-01A (aliquot TCGA-CN-4742-01A-02D-1512-08) from TCGA case TCGA-CN-4742, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 48.7 years (17,793 days).
Specimen TCGA-CN-4742-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 676e2482-b7a2-458e-9eb8-029389d36fbd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-4742-10A (Blood Derived Normal), aliquot TCGA-CN-4742-10A-01D-1512-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0696f65c-b73c-4e31-9bba-3448416fad6f

The open-access MAF lists 71 somatic variants for this specimen: 53 protein-altering or splice-affecting, 15 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 15, Nonsense Mutation 7, 3'UTR 1, Frame Shift Del 1, Frame Shift Ins 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 23/85 reads (27%) | hotspot (GDC flag); catalogued as rs1057520607, CM144128, COSV52689734, COSV52701760, COSV52773998, COSV53851434; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADD2 | c.1970C>T p.T657M | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.425); catalogued as rs371492015; called by muse, mutect2
- AMOT | c.1337G>A p.R446Q (on ENST00000371959 / NM_001113490.1; = p.R37Q on NM_133265.3) | Missense Mutation (SNP) | VAF 79/416 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs1038078287, COSV59062174; called by muse, mutect2, varscan2
- ATRX | c.5455G>C p.D1819H | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100971178; called by muse, mutect2, varscan2
- AXIN2 | c.605G>A p.S202N | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV100196771; called by muse, mutect2, varscan2
- BBS12 | c.1706T>A p.L569Q | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.13); catalogued as COSV100045030; called by muse, mutect2
- CCDC38 | c.709G>T p.A237S | Missense Mutation (SNP) | VAF 19/233 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.106); catalogued as COSV100717760; called by muse, mutect2
- CD163L1 | c.272G>A p.C91Y | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752140168, COSV100550411; called by muse, mutect2, varscan2
- CHM | c.1861T>A p.L621I | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100753505; called by muse, mutect2, varscan2
- CNTNAP3 | c.2179G>C p.E727Q | Missense Mutation (SNP) | VAF 17/270 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.077); catalogued as COSV99904725; called by muse, mutect2
- CUBN | c.358C>G p.L120V | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.725); catalogued as COSV100910593, COSV64701760; called by muse, mutect2, varscan2
- EGFR | c.1423A>G p.I475V | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs1221992080, COSV51825459; called by muse, mutect2, varscan2
- FAM13C | c.893G>T p.R298L | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs534813877, COSV53252651, COSV99513189; called by muse, mutect2, varscan2
- FREM2 | c.4823G>C p.G1608A | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54844884, COSV54845108; called by muse, mutect2
- GABRB2 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as rs373324958, COSV50903874; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPRC6A | c.389A>C p.K130T | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV59954785; called by muse, mutect2, varscan2
- IGKV1D-16 | c.220T>C p.S74P | Missense Mutation (SNP) | VAF 27/283 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as rs759143323; called by muse, mutect2
- INPP5D | c.1778A>G p.D593G (on ENST00000445964 / NM_001017915.3; = p.D592G on NM_005541.5) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as rs1336638244, COSV64038805; called by muse, mutect2, varscan2
- KLHDC8A | c.991G>A p.V331M | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as rs371516364; called by muse, mutect2, varscan2
- LAMA1 | c.6670C>A p.Q2224K | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT tolerated (0.92); PolyPhen benign (0.14); catalogued as COSV67540760; called by muse, mutect2, varscan2
- LECT2 | c.74G>A p.C25Y | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV50846904; called by muse, mutect2, varscan2
- LRRC4C | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 32/134 reads (24%) | catalogued as COSV53426374, COSV53432590; called by muse, mutect2, varscan2
- MAGEC1 | c.2742G>C p.E914D | Missense Mutation (SNP) | VAF 31/377 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV53577539; called by muse, mutect2
- MNDA | c.964T>G p.Y322D | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63741111, COSV63741629; called by muse, mutect2, varscan2
- NAV3 | c.6943C>T p.R2315* (on ENST00000397909 / NM_001024383.2; = p.R2293* on NM_014903.6) | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as rs766836697, COSV57098587; called by muse, mutect2, varscan2
- NEIL3 | c.946A>T p.K316* | Nonsense Mutation (SNP) | VAF 20/190 reads (11%) | catalogued as COSV52812378; called by muse, mutect2, varscan2
- NEK5 | c.328G>T p.V110L | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV62881163; called by muse, mutect2, varscan2
- NETO2 | c.1537C>T p.R513* | Nonsense Mutation (SNP) | VAF 18/182 reads (10%) | catalogued as rs777279280, COSV57454495; called by muse, mutect2, varscan2
- NOTCH1 | c.1264C>T p.P422S | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV53052320, COSV99490172; called by muse, mutect2, varscan2
- OR12D3 | c.512A>C p.K171T | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.471); catalogued as COSV65829256; called by muse, mutect2, varscan2
- PCDH11X | c.1676G>C p.S559T | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53488594; called by muse, mutect2, varscan2
- PLCXD3 | c.749C>A p.T250N | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV60605077, COSV60613593; called by muse, mutect2, varscan2
- PLXNA3 | c.4933C>T p.R1645C | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1557208935, COSV100860107, COSV63754881; called by muse, mutect2, varscan2
- PRKCZ | c.1109G>A p.R370K | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as rs147033679, COSV66069597; called by muse, mutect2
- RPS6KL1 | c.1057G>A p.G353S | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs773733731, COSV63581586, COSV99051301; called by muse, mutect2
- SKP1 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60436239; called by muse, mutect2, varscan2
- SLC9A6 | c.1202T>A p.L401Q | Missense Mutation (SNP) | VAF 12/161 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65788583; called by muse, mutect2
- SRPX2 | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 27/139 reads (19%) | catalogued as COSV65934128; called by muse, mutect2, varscan2
- TANC1 | c.2847A>T p.E949D | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.267); catalogued as COSV55092802; called by muse, mutect2, varscan2
- TBKBP1 | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 24/263 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.228); catalogued as rs767509865, COSV100659175; called by muse, mutect2
- TMEM243 | c.242G>A p.W81* | Nonsense Mutation (SNP) | VAF 13/63 reads (21%) | catalogued as COSV57538983; called by muse, mutect2
- TNFAIP3 | c.1841A>G p.Y614C | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV52797238, COSV52800884; called by muse, mutect2, varscan2
- TOX4 | c.1550A>C p.E517A | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.264); catalogued as COSV52970347; called by muse, mutect2, varscan2
- TTN | c.38379G>T p.E12793D (on ENST00000591111; = p.E5369D on NM_003319.4) | Missense Mutation (SNP) | VAF 29/251 reads (12%) | PolyPhen possibly damaging (0.461); catalogued as COSV60212838; called by muse, mutect2, varscan2
- USP26 | c.2716G>T p.V906L | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV63709268; called by muse, mutect2, varscan2
- USP9X | c.1535G>T p.W512L | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61072641; called by muse, mutect2, varscan2
- XPO1 | c.1834G>A p.D612N | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.331); catalogued as COSV68946921; called by muse, mutect2, varscan2
- XYLT1 | c.440G>C p.R147P | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.033); catalogued as COSV54491423; called by muse, mutect2, varscan2
- ZBTB16 | c.1947G>A p.M649I | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV60096890; called by muse, mutect2
- ZIC4 | c.919G>A p.V307M | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as rs573214910, COSV67172137, COSV67174127; called by muse, mutect2, varscan2
- ZNF280A | c.552G>C p.R184S | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57481527; called by muse, mutect2, varscan2
- ZBTB38 | c.3284_3285del p.H1095Lfs*26 | Frame Shift Del (DEL) | VAF 26/119 reads (22%) | called by mutect2, pindel, varscan2
- ZSCAN29 | c.818dup p.H273Qfs*2 | Frame Shift Ins (INS) | VAF 17/129 reads (13%) | called by mutect2, pindel, varscan2
- CDK5R1 | c.672C>T p.A224= | Silent (SNP) | VAF 39/256 reads (15%) | catalogued as COSV55579373; called by muse, mutect2, varscan2
- COL6A3 | c.7254C>T p.F2418= | Silent (SNP) | VAF 18/161 reads (11%) | catalogued as rs768794876, COSV55080829, COSV55088019; ClinVar: likely benign; called by muse, mutect2, varscan2
- FANCE | c.549T>C p.A183= | Silent (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- HRNR | c.1674T>C p.Y558= | Silent (SNP) | VAF 30/206 reads (15%) | catalogued as rs1244189064, COSV64260674; called by muse, mutect2, varscan2
- KEAP1 | c.846G>A p.Q282= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as rs996259514, COSV50483560; called by muse, mutect2, varscan2
- L1CAM | c.2919C>T p.P973= | Silent (SNP) | VAF 47/349 reads (13%) | catalogued as rs375705679, CD099763, COSV62829163; called by muse, mutect2, varscan2
- MUC16 | c.22755A>T p.T7585= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as COSV67480596; called by muse, mutect2, varscan2
- OLFM3 | c.453C>T p.D151= (on ENST00000338858 / NM_001288821.1; = p.D131= on NM_058170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs201734752, COSV58801441; called by mutect2, varscan2
- PDXDC1 | c.1260G>A p.R420= | Silent (SNP) | VAF 5/77 reads (6%) | catalogued as rs773936654, COSV57909785; called by muse, mutect2
- RAB5B | c.126A>G p.K42= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as COSV64365083; called by muse, mutect2, varscan2
- RADIL | c.1671G>A p.A557= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as rs767642627, COSV68200012, COSV68202503; called by muse, mutect2, varscan2
- RBM27 | c.2175C>T p.H725= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as rs774696778, COSV54591451; called by muse, mutect2, varscan2
- THSD7A | c.1371G>A p.G457= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs1001942368, COSV70269100, COSV70273759; called by muse, mutect2, varscan2
- TMEM132D | c.657G>A p.P219= | Silent (SNP) | VAF 11/108 reads (10%) | catalogued as rs143084996, COSV70595636; called by muse, mutect2, varscan2
- ZNF527 | c.1401A>G p.E467= | Silent (SNP) | VAF 4/71 reads (6%) | catalogued as COSV62232908; called by muse, mutect2
- CT55 | c.-2C>T | 5'UTR (SNP) | VAF 15/125 reads (12%) | catalogued as rs782419674, COSV99358924; called by muse, mutect2, varscan2
- MIR526A1 | n.57C>T | RNA (SNP) | VAF 17/111 reads (15%) | catalogued as rs375955707; called by muse, mutect2, varscan2
- XIRP2 | c.*973A>T | 3'UTR (SNP) | VAF 9/81 reads (11%) | catalogued as COSV54719404; called by muse, mutect2, varscan2
